Somatic mutation profile of tumor specimen TCGA-GU-AATP-01A (aliquot TCGA-GU-AATP-01A-11D-A391-08) from TCGA case TCGA-GU-AATP, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,049 days).
Specimen TCGA-GU-AATP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8775d59-908c-48da-8edc-e9bb31eaa1fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-AATP-10A (Blood Derived Normal), aliquot TCGA-GU-AATP-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6de4846e-15e1-4fca-8635-3baa49be26c6

The open-access MAF lists 359 somatic variants for this specimen: 270 protein-altering or splice-affecting, 82 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 82, Nonsense Mutation 26, Splice Site 8, Frame Shift Del 5, Intron 3, In Frame Del 2, Splice Region 2, Frame Shift Ins 2, RNA 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.2989G>T p.A997S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs137854609, CM014388, CM100685, COSV61119231; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TSC1 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 42/68 reads (62%) | catalogued as rs1554817388, CM1412332, COSV100051580; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1434C>G p.I478M (on ENST00000404938 / NM_001163941.2; = p.I33M on NM_178559.6) | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51705699; called by muse, mutect2, varscan2
- ABCC11 | c.758T>A p.I253K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62321903; called by muse, mutect2, varscan2
- ABHD8 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV56044379; called by muse, mutect2, varscan2
- ABI3 | c.697C>G p.P233A | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56799506; called by muse, mutect2, varscan2
- ACTB | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59316730; called by muse, mutect2, varscan2
- ADAM12 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs200657108, COSV64101988; called by muse, mutect2, varscan2
- ADAM30 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65560612, COSV65561734; called by muse, mutect2, varscan2
- ADGRG1 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs773923883, COSV65635338; called by muse, mutect2, varscan2
- AGFG2 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53544448; called by muse, mutect2
- AHNAK | c.14110C>G p.L4704V | Missense Mutation (SNP) | VAF 157/303 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); catalogued as COSV57207447; called by muse, mutect2, varscan2
- AL592490.1 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69425276, COSV69425902; called by muse, mutect2
- ALG1L | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.914); catalogued as COSV61075443; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6542C>T p.S2181L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV51842827; called by muse, mutect2, varscan2
- ARID1B | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); catalogued as COSV51653596; called by muse, mutect2, varscan2
- ATP13A1 | c.3236G>T p.R1079L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV52283833; called by muse, mutect2, varscan2
- BAK1 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV100645890; called by muse, mutect2, varscan2
- BAZ2B | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV58597411; called by muse, mutect2, varscan2
- BRCA2 | c.10213G>C p.E3405Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as rs1555290071, COSV58412399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF3 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.992); catalogued as COSV60206557, COSV60209866; called by muse, mutect2, varscan2
- C12orf4 | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.213); catalogued as COSV54206132; called by muse, mutect2, varscan2
- CACNA1A | c.5029C>T p.L1677F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64192798; called by muse, mutect2
- CADPS | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs772655154, COSV51871856; called by muse, mutect2, varscan2
- CARD8 | c.1594C>T p.L532F (on ENST00000651546 / NM_001184900.3; = p.L482F on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62873076; called by muse, mutect2, varscan2
- CASP8 | c.344C>T p.S115L (on ENST00000432109 / NM_033355.3; = p.S147L on NM_001228.4) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV51847755, COSV51852205; called by muse, mutect2
- CCDC54 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV53758197; called by muse, mutect2, varscan2
- CCDC71 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs773425388, COSV58909937; called by muse, mutect2, varscan2
- CCER1 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 16/150 reads (11%) | catalogued as rs574692889, COSV100727162, COSV62646194, COSV62646946; called by muse, mutect2, varscan2
- CCHCR1 | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV66183204; called by muse, mutect2, varscan2
- CCHCR1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs996478108, COSV66161172; called by muse, varscan2
- CCNE1 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV52903827; called by muse, mutect2, varscan2
- CCNG2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV100313315, COSV60353280; called by muse, mutect2, varscan2
- CDH16 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV55335612; called by muse, mutect2, varscan2
- CDKAL1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV51181063; called by muse, mutect2, varscan2
- CEP152 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100359150; called by muse, mutect2, varscan2
- CMYA5 | c.4237C>G p.L1413V | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV71406988; called by muse, mutect2
- COL11A2 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs1440032367, COSV100554514; called by muse, mutect2
- COL16A1 | c.1059G>C p.E353D | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV99595439; called by muse, mutect2
- COL3A1 | c.2392-1G>A p.X798_splice | Splice Site (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100483217, COSV58584312; called by muse, mutect2, varscan2
- COL6A3 | c.6412G>C p.D2138H | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.888); catalogued as rs1166106380, COSV55083554; called by muse, mutect2, varscan2
- COL6A6 | c.276C>A p.N92K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV62020513; called by muse, mutect2, varscan2
- CPA6 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52724205; called by muse, mutect2, varscan2
- CPEB3 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 41/168 reads (24%) | catalogued as COSV99800619; called by muse, mutect2, varscan2
- CPSF1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs1554864545, COSV58236021; called by muse, mutect2
- CRYBG1 | c.5461A>G p.R1821G | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.143); catalogued as COSV64811283; called by muse, mutect2, varscan2
- CRYBG2 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV57484509; called by muse, mutect2, varscan2
- CRYBG2 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs368402676, COSV57484515; called by muse, mutect2, varscan2
- CSMD3 | c.10672C>T p.L3558F (on ENST00000297405 / NM_001363185.1; = p.L3389F on NM_052900.3) | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52131699, COSV52175526, COSV99847705; called by muse, mutect2, varscan2
- CSPG4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV57892384; called by muse, mutect2, varscan2
- CYP11B2 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV59995197, COSV59995273; called by muse, mutect2, varscan2
- CYP4A11 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV60222610; called by muse, mutect2, varscan2
- CYP7A1 | c.1388C>G p.S463C | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV56962863; called by muse, mutect2
- DDX50 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as rs760232514, COSV65291971; called by muse, mutect2, varscan2
- DENND4B | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs369938170; called by muse, mutect2, varscan2
- DHDDS | c.914G>C p.R305T (on ENST00000236342 / NM_001319959.1; = p.R306T on NM_024887.3) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV52575841; called by muse, mutect2, varscan2
- DHX36 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV57671464; called by muse, mutect2, varscan2
- DMXL1 | c.5325G>C p.M1775I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV60707247; called by muse, mutect2, varscan2
- DNAH7 | c.7397G>T p.R2466L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs770220298, COSV56756557, COSV56767044; called by muse, mutect2, varscan2
- DOCK3 | c.4240G>A p.D1414N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs752676188, COSV99815034; called by muse, mutect2
- DOCK6 | c.4889A>G p.Y1630C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1209305611, COSV99626668; called by muse, mutect2, varscan2
- DRC1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as rs1271834382, COSV99985717; called by muse, mutect2, varscan2
- EFCAB3 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 45/82 reads (55%) | catalogued as rs544369412, COSV100540484; called by muse, mutect2, varscan2
- EFTUD2 | c.2509C>T p.Q837* | Nonsense Mutation (SNP) | VAF 69/137 reads (50%) | catalogued as COSV99494039; called by muse, mutect2, varscan2
- EHMT2 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV64995034; called by muse, varscan2
- EIF2AK4 | c.2152_2153insTG p.S718Lfs*74 | Frame Shift Ins (INS) | VAF 24/65 reads (37%) | catalogued as COSV55466358; called by mutect2, pindel*, varscan2
- EIF4G1 | c.4190G>T p.R1397L (on ENST00000346169 / NM_198241.3; = p.R1202L on NM_004953.5) | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV59989827; called by muse, mutect2, varscan2
- ELF3 | c.478+1_478+3del p.X160_splice | Splice Site (DEL) | VAF 20/57 reads (35%) | catalogued as rs995289305; called by mutect2, pindel, varscan2
- EP300 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99608888; called by muse, mutect2, varscan2
- EPG5 | c.7375G>A p.E2459K | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV56346613; called by muse, mutect2, varscan2
- ETV6 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs772696896, COSV67148724; called by muse, mutect2, varscan2
- EXOC1 | c.1540-1G>C p.X514_splice | Splice Site (SNP) | VAF 15/39 reads (38%) | catalogued as rs1290729531, COSV62119551; called by muse, mutect2, varscan2
- EXOSC10 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV58664361; called by muse, mutect2, varscan2
- FAM122C | c.224G>C p.S75T | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as COSV66194818; called by muse, mutect2, varscan2
- FAM135B | c.3290del p.Q1097Rfs*10 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as COSV52712992; called by mutect2, pindel, varscan2
- FAM177A1 | c.469G>A p.E157K (on ENST00000382406 / NM_001289022.2; = p.E180K on NM_173607.5) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV54831849; called by muse, varscan2
- FAR2 | c.1385+2T>G p.X462_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV51724256; called by muse, mutect2, varscan2
- FASN | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.231); catalogued as COSV60751890; called by muse, mutect2, varscan2
- FCHSD1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV71300610; called by muse, mutect2, varscan2
- FKBP5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1403366116, COSV61880631; called by muse, mutect2, varscan2
- FLG | c.6905C>G p.S2302* | Nonsense Mutation (SNP) | VAF 145/510 reads (28%) | catalogued as COSV100912187; called by muse, mutect2, varscan2
- FLG2 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV66167295; called by muse, mutect2, varscan2
- FRMD8 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.505); catalogued as COSV58212034; called by muse, mutect2, varscan2
- FRMD8 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV58212048; called by muse, mutect2, varscan2
- FSD1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772189489, COSV55695204, COSV99696636; called by muse, mutect2, varscan2
- FSIP1 | c.353C>A p.A118D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63223895; called by muse, mutect2, varscan2
- GALNT12 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV66662315, COSV66663283; called by muse, mutect2, varscan2
- GALNTL6 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV72490060, COSV72491800; called by muse, mutect2, varscan2
- GBX2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as rs1489758659, COSV60444976; called by muse, mutect2, varscan2
- GCNT3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV68532032; called by muse, mutect2, varscan2
- GDPD4 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60017975; called by muse, mutect2, varscan2
- GNAI1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100650625; called by muse, mutect2, varscan2
- GNL2 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 40/80 reads (50%) | catalogued as COSV99953752; called by muse, mutect2, varscan2
- GPR119 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.437); catalogued as COSV52275241; called by muse, mutect2, varscan2
- GPS2 | c.397+2T>G p.X133_splice | Splice Site (SNP) | VAF 59/96 reads (61%) | catalogued as COSV59748112; called by muse, mutect2, varscan2
- GSK3B | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV51772486; called by muse, mutect2, varscan2
- GTF2I | c.1935-1G>A p.X645_splice (on ENST00000573035 / NM_032999.4; = p.X604_splice on NM_001518.5) | Splice Site (SNP) | VAF 12/92 reads (13%) | catalogued as COSV60400190; called by mutect2, varscan2
- GTF3C1 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV55176034; called by muse, mutect2, varscan2
- GUCD1 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV68034934; called by muse, mutect2, varscan2
- H2AC15 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV57585189; called by muse, mutect2, varscan2
- H2BC17 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as COSV58152239; called by muse, mutect2, varscan2
- H2BC8 | c.139A>T p.K47* | Nonsense Mutation (SNP) | VAF 37/184 reads (20%) | catalogued as rs759051084, COSV99773394; called by muse, mutect2, varscan2
- H3C13 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV58943981; called by muse, mutect2, varscan2
- HADH | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1237134068, COSV58847508; called by muse, mutect2, varscan2
- HERC1 | c.5480G>C p.G1827A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1567021793, COSV101496901, COSV71245997; called by muse, mutect2
- HIF1A | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60188555; called by muse, mutect2, varscan2
- HIPK3 | c.3159G>C p.L1053F | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV57561519; called by muse, mutect2, varscan2
- HMOX2 | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99566701; called by muse, mutect2, varscan2
- HOXC9 | c.313T>A p.S105T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as COSV57716539; called by muse, mutect2, varscan2
- HPN | c.938G>C p.R313P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.589); catalogued as rs770594847, COSV52882625; called by muse, mutect2
- HSD17B14 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV54412787; called by muse, mutect2, varscan2
- HSPA12B | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.417); catalogued as COSV54766042; called by muse, mutect2, varscan2
- HSPA1B | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV65128241; called by muse, mutect2, varscan2
- HSPA1L | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs750047577, COSV65148787; called by muse, mutect2, varscan2
- IFT172 | c.4122G>C p.W1374C | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53131346; called by muse, mutect2, varscan2
- IFT172 | c.4037G>C p.G1346A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.167); catalogued as COSV53131362; called by muse, mutect2, varscan2
- IGSF22 | c.1784C>G p.S595C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as rs368557709; called by muse, mutect2, varscan2
- IMPG2 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV51975204; called by muse, mutect2, varscan2
- INTS1 | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 85/163 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV67176772; called by muse, mutect2, varscan2
- INTS3 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775136705, COSV59675960; called by muse, mutect2, varscan2
- IPP | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739432, COSV63432144, COSV63432196; called by muse, mutect2, varscan2
- ITGA4 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as COSV99276803; called by muse, mutect2, varscan2
- ITGAE | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 112/170 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1335009363, COSV53990843; called by muse, mutect2, varscan2
- ITGAE | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1465097576, COSV53990851; called by muse, mutect2, varscan2
- ITPRIP | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV53390995; called by muse, mutect2, varscan2
- KCNC3 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs1449420106, COSV100979379; called by muse, varscan2
- KDM6A | c.2953T>C p.S985P | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65038070, COSV65038291; called by muse, mutect2, varscan2
- KIFAP3 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs760961099, COSV100847162; called by muse, mutect2
- KIFC1 | c.1085G>C p.G362A | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.329); catalogued as COSV65737388; called by muse, mutect2, varscan2
- KMT2C | c.12340G>A p.E4114K | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51419906; called by muse, mutect2, varscan2
- KMT2D | c.16460C>A p.T5487K | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56421678; called by muse, mutect2, varscan2
- L3MBTL1 | c.645C>G p.F215L (on ENST00000418998 / NM_001377303.1; = p.F125L on NM_015478.7) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.341); catalogued as COSV64231021; called by muse, mutect2, varscan2
- LAMA5 | c.7147G>A p.D2383N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV53355504; called by muse, mutect2, varscan2
- LIPC | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.499); catalogued as rs1229406789, COSV54421146, COSV54424342; called by muse, mutect2, varscan2
- LMTK3 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99541202; called by muse, mutect2
- LRG1 | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV56702832; called by muse, mutect2, varscan2
- LRIG3 | c.3010C>G p.H1004D | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV57861862; called by muse, mutect2, varscan2
- LRP1B | c.12719G>T p.W4240L | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.994); catalogued as COSV67195157, COSV67198511; called by muse, mutect2
- LRP2 | c.12194G>C p.R4065P | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV55545930, COSV55549941; called by muse, mutect2, varscan2
- LRRFIP2 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60866783; called by muse, mutect2, varscan2
- LRRTM3 | c.731T>A p.I244K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63662911; called by muse, mutect2, varscan2
- LSG1 | c.1910G>A p.W637* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV99503544; called by muse, mutect2
- LZTS2 | c.1100G>C p.R367P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV100932280, COSV64651088; called by mutect2, varscan2
- MAD2L1 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1261027768, COSV56636668; called by muse, mutect2, varscan2
- MAP1S | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.83); catalogued as rs754821624, COSV60722030; called by muse, mutect2, varscan2
- MAPK10 | c.1068C>G p.I356M (on ENST00000359221 / NM_001351625.2; = p.I394M on NM_002753.5) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV60378288; called by muse, mutect2, varscan2
- MCM8 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1288087625, COSV52543053; called by muse, mutect2, varscan2
- MFSD1 | c.1038G>A p.M346I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs759738376, COSV51839720; called by muse, mutect2, varscan2
- MMP17 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs1270337512, COSV62178707, COSV62180913; called by muse, mutect2
- MRGPRX1 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs1463450834, COSV57109601; called by muse, mutect2, varscan2
- MRS2 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV51234085; called by muse, mutect2, varscan2
- MS4A8 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 96/180 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV55753524; called by muse, mutect2, varscan2
- MUC17 | c.5230C>T p.P1744S | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1336352446, COSV60283155; called by muse, mutect2
- MUC4 | c.13708C>T p.R4570W (on ENST00000463781 / NM_018406.7; = p.R334W on NM_004532.6) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.448); catalogued as rs752454108, COSV57772048; called by muse, mutect2, varscan2
- MYH15 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV56306332; called by muse, mutect2, varscan2
- MYH7B | c.4198G>A p.E1400K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52678019; called by muse, mutect2, varscan2
- MYO7B | c.2169G>A p.M723I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.268); catalogued as COSV67345693; called by muse, mutect2, varscan2
- MYPN | c.1928C>G p.S643C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV62732265, COSV62740025; called by muse, mutect2, varscan2
- NCOA1 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.073); catalogued as COSV56041063, COSV56042990; called by muse, varscan2
- NCOR1 | c.3013del p.E1005Kfs*10 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | catalogued as COSV51965634; called by mutect2, pindel, varscan2
- NEK11 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1203598520, COSV63579673; called by muse, mutect2, varscan2
- NEO1 | c.3583C>A p.Q1195K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56068937; called by muse, mutect2, varscan2
- NFATC3 | c.528C>G p.F176L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.365); catalogued as COSV60471933; called by muse, mutect2, varscan2
- NIPA2 | c.194C>G p.S65* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV100508932; called by muse, mutect2, varscan2
- NMD3 | c.124A>T p.I42F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63618330; called by muse, mutect2
- NMNAT2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs764247192, COSV54267222; called by muse, mutect2, varscan2
- NRG1 | c.1856C>A p.S619* (on ENST00000405005 / NM_013964.5; = p.S624* on NM_013956.5) | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99828588, COSV99829522; called by muse, mutect2, varscan2
- NUP210L | c.3559A>G p.T1187A | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV55144023; called by muse, mutect2, varscan2
- ODF3L1 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.679); catalogued as COSV59819976; called by muse, mutect2, varscan2
- OR12D2 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV101011471; called by muse, mutect2, varscan2
- OR2B11 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV59509624; called by muse, mutect2
- OR2L8 | c.322G>C p.G108R | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV61726020; called by muse, mutect2
- OR51B4 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV66516956; called by muse, mutect2, varscan2
- PAGE4 | c.210G>C p.K70N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54334523; called by muse, mutect2
- PCDHA1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV65373234; called by muse, mutect2, varscan2
- PCDHA6 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as COSV65342815; called by muse, mutect2, varscan2
- PCDHB10 | c.1240A>G p.R414G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as COSV53376648; called by muse, mutect2, varscan2
- PCDHB6 | c.1667C>G p.S556W | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV50690992, COSV50691788; called by muse, mutect2, varscan2
- PCF11 | c.4177G>C p.E1393Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1454154892, COSV100019232; called by muse, mutect2, varscan2
- PCGF2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1412816395; called by muse, mutect2, varscan2
- PGP | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57027175; called by muse, mutect2, varscan2
- PHLPP1 | c.3453G>A p.L1151= | Splice Region (SNP) | VAF 8/21 reads (38%) | catalogued as rs763286521, COSV53024745; called by muse, mutect2, varscan2
- PKHD1 | c.11153C>T p.S3718L | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100943388, COSV64383925; called by muse, mutect2, varscan2
- PLA2G4C | c.1626G>C p.*542Yext*15 | Nonstop Mutation (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99506718; called by muse, mutect2, varscan2
- PM20D1 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV65648572; called by muse, mutect2, varscan2
- PPP1CA | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56702223, COSV56704938; called by muse, mutect2, varscan2
- PRCC | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54855554; called by muse, mutect2, varscan2
- PRG4 | c.4054_4059del p.S1352_A1353del | In Frame Del (DEL) | VAF 24/112 reads (21%) | catalogued as COSV63355127; called by mutect2, pindel, varscan2
- PRPF31 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV58084786; called by muse, mutect2, varscan2
- PSD | c.2091G>A p.K697= | Splice Region (SNP) | VAF 17/75 reads (23%) | catalogued as COSV50042873; called by muse, mutect2, varscan2
- PTCH1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV59467273; called by muse, mutect2, varscan2
- PTPRZ1 | c.5167-1G>C p.X1723_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as COSV66432856; called by muse, mutect2, varscan2
- PUF60 | c.1382C>G p.S461C (on ENST00000526683 / NM_001362896.2; = p.S444C on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV57584194; called by muse, mutect2, varscan2
- RABGAP1L | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV52283512; called by muse, mutect2
- RAD51 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV51111261; called by muse, mutect2
- RARA | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54190709; called by muse, mutect2
- RP1L1 | c.3685G>A p.E1229K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs924464860, COSV66753100; called by muse, mutect2, varscan2
- RUSC1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99430287; called by muse, mutect2
- RUSC1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.432); catalogued as COSV52738777; called by muse, mutect2, varscan2
- SCAMP4 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100290728, COSV60190444; called by muse, mutect2, varscan2
- SEC23IP | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); catalogued as rs745892335, COSV64831018; called by muse, mutect2, varscan2
- SEC31B | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100947461; called by muse, mutect2
- SESN3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV53583791; called by muse, mutect2, varscan2
- SESN3 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.562); catalogued as COSV53583807; called by muse, mutect2, varscan2
- SETDB1 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV54978791; called by muse, mutect2, varscan2
- SGK3 | c.1379A>G p.Y460C | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); catalogued as COSV61894051; called by muse, mutect2, varscan2
- SIRPD | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV101064904, COSV67546399; called by muse, mutect2
- SLC2A2 | c.828G>C p.M276I | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV58585172; called by muse, mutect2, varscan2
- SLC35F3 | c.112G>A p.E38K (on ENST00000366617 / NM_001300845.1; = p.E107K on NM_173508.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV64018718; called by muse, mutect2, varscan2
- SLC7A10 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53502946, COSV99471919; called by muse, mutect2, varscan2
- SLC8B1 | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs911520340, COSV52526812; called by muse, mutect2, varscan2
- SLMAP | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99909258; called by muse, mutect2, varscan2
- SNX3 | c.415C>A p.R139S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV57778449; called by muse, mutect2, varscan2
- SOS1 | c.3855T>G p.H1285Q | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV67674354; called by muse, mutect2, varscan2
- SPDYC | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65865016; called by muse, mutect2, varscan2
- SPNS1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248994123, COSV57954047; called by muse, mutect2, varscan2
- SRPK3 | c.282G>C p.W94C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99473432; called by muse, mutect2, varscan2
- STAB2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs576972879, COSV66336271; called by muse, mutect2, varscan2
- STON1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1456738136, COSV59126200; called by muse, mutect2, varscan2
- SUSD5 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs776179774, COSV58875454; called by muse, mutect2, varscan2
- SVIL | c.4960G>A p.G1654R (on ENST00000355867 / NM_021738.3; = p.G1228R on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV63441363; called by muse, varscan2
- TAF1L | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147409173, COSV54260040; called by muse, mutect2, varscan2
- TANC2 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV101267675; called by muse, mutect2, varscan2
- TBX10 | c.549+1G>A p.X183_splice | Splice Site (SNP) | VAF 32/109 reads (29%) | catalogued as rs775096048, COSV56875260, COSV56875516; called by muse, mutect2, varscan2
- TEAD3 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58816111; called by muse, mutect2, varscan2
- TESK2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as rs145725484, COSV59150271; called by muse, mutect2, varscan2
- TFB1M | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as COSV100905244; called by muse, mutect2
- TIFAB | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV72345710; called by muse, mutect2, varscan2
- TIPIN | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56019619; called by muse, mutect2
- TNC | c.5190G>A p.W1730* | Nonsense Mutation (SNP) | VAF 36/65 reads (55%) | catalogued as COSV100406264; called by muse, mutect2, varscan2
- TNC | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV60782172; called by muse, mutect2, varscan2
- TNK2 | c.2556G>C p.K852N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57367160; called by muse, mutect2, varscan2
- TNK2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1207341396, COSV57367172; called by muse, mutect2, varscan2
- TP53 | c.566_582del p.A189Dfs*14 | Frame Shift Del (DEL) | VAF 22/35 reads (63%) | catalogued as COSV52832901; called by mutect2, pindel, varscan2
- TP53BP1 | c.5158G>T p.G1720W | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55498050; called by muse, mutect2, varscan2
- TSEN54 | c.1284G>C p.Q428H | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV51344355; called by muse, mutect2, varscan2
- UBC | c.1949G>A p.R650K | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV60058745; called by muse, mutect2
- UBC | c.1947G>T p.Q649H | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60058755; called by muse, mutect2
- UBC | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100298900, COSV60058767; called by muse, varscan2
- UNC79 | c.6243C>A p.F2081L (on ENST00000393151 / NM_001346218.2; = p.F1904L on NM_020818.5) | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1444208663, COSV56371880, COSV56379288; called by muse, mutect2, varscan2
- USP37 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs778090135, COSV51442053; called by muse, mutect2, varscan2
- USP47 | c.844G>A p.D282N (on ENST00000399455 / NM_001372095.1; = p.D194N on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60461930; called by muse, mutect2, varscan2
- USP48 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100380247, COSV100380393; called by muse, mutect2, varscan2
- UTRN | c.2872G>C p.E958Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.085); catalogued as rs1331233214, COSV62330319; called by muse, varscan2
- UTRN | c.2947G>C p.E983Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV62330325; called by muse, varscan2
- VPS33A | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV57356412; called by muse, mutect2
- VWA8 | c.3541C>G p.Q1181E | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV64994688; called by muse, mutect2, varscan2
- WDR64 | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV63793657; called by muse, mutect2
- WDR75 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as COSV59104963; called by muse, mutect2, varscan2
- WDTC1 | c.957G>C p.Q319H (on ENST00000319394 / NM_001276252.2; = p.Q318H on NM_015023.5) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as COSV60087583, COSV60088880; called by muse, mutect2, varscan2
- WSCD2 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1361470794, COSV54579241; called by muse, mutect2, varscan2
- YTHDF2 | c.882G>C p.Q294H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.497); catalogued as rs1257533090, COSV65722953; called by muse, mutect2, varscan2
- YTHDF2 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100863778, COSV65722962; called by muse, mutect2, varscan2
- ZBTB26 | c.885C>G p.H295Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65402973; called by muse, mutect2, varscan2
- ZBTB32 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214931485, COSV52889899; called by muse, mutect2, varscan2
- ZNF101 | c.312C>A p.C104* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV100543634; called by muse, mutect2, varscan2
- ZNF221 | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.203); catalogued as COSV52108611; called by muse, mutect2
- ZNF281 | c.2420C>G p.S807C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV54166289; called by muse, mutect2
- ZNF576 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.684); catalogued as rs764776830, COSV60670366; called by muse, mutect2, varscan2
- ZNF623 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV71697113, COSV71697119; called by muse, mutect2, varscan2
- ZNF638 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52483789; called by muse, mutect2, varscan2
- ZNF680 | c.1529A>C p.K510T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.324); catalogued as COSV59014478, COSV59016930; called by muse, mutect2
- ZNHIT3 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1351903527; called by muse, varscan2
- ZSWIM8 | c.4773del p.H1591Qfs*22 (on ENST00000605216 / NM_001242487.2; = p.H1596Qfs*22 on NM_015037.3) | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as COSV55213375; called by mutect2, pindel, varscan2
- CD33 | c.819_820delinsA p.C274Vfs*8 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by pindel, varscan2*
- CTR9 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2
- FCGBP | c.9452G>A p.C3151Y | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP5L | c.2220_2225del p.L741_E742del | In Frame Del (DEL) | VAF 59/142 reads (42%) | called by mutect2, pindel, varscan2
- TADA2A | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2
- ZFP36L1 | c.966_967dup p.N323Tfs*40 (on ENST00000336440 / NM_001244698.1; = p.N323Tfs*21 on NM_004926.4) | Frame Shift Ins (INS) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- A2ML1 | c.166C>T p.L56= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV55287595; called by muse, mutect2, varscan2
- ADGRL1 | c.153C>T p.P51= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs149580055; called by muse, mutect2, varscan2
- AGAP4 | c.558G>A p.G186= | Silent (SNP) | VAF 35/44 reads (80%) | called by mutect2, varscan2
- AGFG2 | c.591C>T p.V197= | Silent (SNP) | VAF 12/171 reads (7%) | catalogued as COSV53544456; called by muse, mutect2
- APOA4 | c.756C>G p.L252= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV63360201; called by muse, mutect2, varscan2
- ARFGAP1 | c.1068C>T p.T356= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs762905409, COSV62262645; called by muse, mutect2, varscan2
- ARFGEF3 | c.528G>A p.Q176= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV52452632; called by muse, mutect2, varscan2
- ARHGEF19 | c.219C>T p.L73= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV54615590; called by muse, mutect2, varscan2
- ATP6V1B1 | c.798C>T p.I266= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs368632513, COSV52268596; called by muse, mutect2, varscan2
- C2CD5 | c.810C>T p.F270= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV61723646; called by muse, mutect2, varscan2
- CABP5 | c.423G>A p.R141= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs1273853885, COSV53152270; called by muse, mutect2, varscan2
- CACNA1S | c.168C>T p.I56= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV62937654; called by muse, mutect2
- CLCN1 | c.279G>A p.E93= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV100578691, COSV58368407; called by muse, mutect2, varscan2
- CNOT4 | c.399G>A p.G133= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as rs1430159385, COSV59650810; called by muse, mutect2, varscan2
- CRYBG3 | c.8124C>T p.L2708= | Silent (SNP) | VAF 14/185 reads (8%) | catalogued as rs775248236, COSV51710357; called by muse, mutect2
- CXADR | c.66C>A p.I22= | Silent (SNP) | VAF 45/84 reads (54%) | catalogued as COSV53028262, COSV53029926; called by muse, mutect2, varscan2
- DDB2 | c.111C>G p.L37= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV57037522; called by muse, mutect2, varscan2
- DES | c.909G>A p.L303= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs754852794, COSV64660009; called by muse, mutect2, varscan2
- DGKZ | c.2967G>A p.R989= (on ENST00000454345 / NM_001105540.2; = p.R801= on NM_003646.4) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV58986289; called by muse, mutect2, varscan2
- DNM2 | c.1458C>T p.I486= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as COSV58958486, COSV58965644; called by muse, varscan2
- DPYD | c.1917T>G p.A639= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV64593180; called by muse, mutect2, varscan2
- DTX4 | c.1665C>T p.L555= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV57089292, COSV57092358; called by muse, mutect2, varscan2
- DUSP9 | c.393G>A p.Q131= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV61437855; called by muse, mutect2, varscan2
- EFEMP2 | c.279C>T p.G93= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs769750626, COSV57259503; ClinVar: uncertain significance; called by muse, mutect2
- EMC10 | c.294C>G p.L98= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100618550; called by muse, mutect2
- ENO2 | c.147G>A p.L49= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV50387257; called by muse, mutect2, varscan2
- FDXR | c.1290C>T p.L430= (on ENST00000293195 / NM_024417.5; = p.L436= on NM_004110.6) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs759231758, COSV53110805; called by muse, mutect2, varscan2
- GATAD2A | c.1071G>A p.E357= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53067976; called by muse, mutect2, varscan2
- GJB7 | c.327C>G p.L109= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV51529099; called by muse, mutect2, varscan2
- H4C9 | c.294C>T p.L98= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV62889669; called by muse, mutect2, varscan2
- HSPG2 | c.12780C>T p.I4260= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV60827764; called by muse, mutect2, varscan2
- IGF2R | c.2166G>A p.P722= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs757629355, COSV63627262; called by muse, mutect2
- ITPR3 | c.2547G>A p.V849= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs776612517, COSV100967068, COSV65407011; called by muse, mutect2, varscan2
- KIF1A | c.1524C>T p.L508= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV57485225; called by muse, mutect2, varscan2
- KRT40 | c.1080G>A p.E360= | Silent (SNP) | VAF 182/292 reads (62%) | catalogued as rs1420875159, COSV66696132; called by muse, mutect2, varscan2
- LLPH | c.342G>A p.G114= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as COSV56981485; called by muse, mutect2, varscan2
- LRRC49 | c.1950G>A p.Q650= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV53009032; called by muse, mutect2, varscan2
- MADD | c.2649G>C p.L883= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV60621766; called by muse, mutect2
- MAP3K15 | c.1287G>A p.R429= | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as COSV58827303; called by muse, mutect2, varscan2
- MRGPRX3 | c.861G>A p.L287= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV66933382; called by muse, mutect2, varscan2
- MTMR2 | c.313C>T p.L105= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV60578934; called by muse, mutect2, varscan2
- MUSK | c.1086G>C p.V362= | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as COSV51880506; called by muse, mutect2, varscan2
- NRROS | c.144C>A p.L48= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs146517885, COSV60745090; called by muse, mutect2, varscan2
- OBI1 | c.40C>T p.L14= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs778683718, COSV56144951; called by muse, mutect2, varscan2
- PCBP4 | c.492C>T p.R164= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV59054041; called by muse, mutect2, varscan2
- PCDHGB7 | c.1659C>T p.G553= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53916243; called by muse, mutect2, varscan2
- PDE4DIP | c.4983C>T p.T1661= | Silent (SNP) | VAF 22/280 reads (8%) | catalogued as rs1460221916, COSV57684243; called by muse, mutect2
- PEX6 | c.1824C>G p.L608= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55101885; called by muse, mutect2, varscan2
- POLR2E | c.391C>T p.L131= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV53123590; called by muse, mutect2, varscan2
- PPARD | c.981C>T p.I327= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV61099116; called by muse, mutect2, varscan2
- PPP1R7 | c.96G>A p.G32= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV52143958; called by muse, mutect2, varscan2
- PPP1R8 | c.258A>C p.I86= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV52579645; called by muse, mutect2, varscan2
- RCAN2 | c.228C>T p.F76= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs770580714, COSV57815273, COSV57815906; called by muse, mutect2, varscan2
- RPTOR | c.3291G>A p.K1097= | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as COSV60802992; called by muse, mutect2, varscan2
- RYR3 | c.3387G>A p.Q1129= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV66782073; called by muse, mutect2, varscan2
- SCARF2 | c.1401C>T p.C467= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1256491835, COSV99839453; called by muse, mutect2
- SEPTIN5 | c.228C>G p.L76= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1470365316, COSV63530463; called by muse, mutect2, varscan2
- SFRP2 | c.765G>A p.A255= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs534229867, COSV56837119; called by muse, mutect2, varscan2
- SLC35F3 | c.1212G>C p.L404= (on ENST00000366617 / NM_001300845.1; = p.L473= on NM_173508.4) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV64018725; called by muse, mutect2
- SLC45A1 | c.1017G>T p.S339= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99239608; called by muse, mutect2, varscan2
- SLCO3A1 | c.1818G>T p.T606= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs144388319, COSV59226842; called by muse, mutect2, varscan2
- SPART | c.1872C>T p.L624= | Silent (SNP) | VAF 32/186 reads (17%) | catalogued as rs1302866280, COSV62084181; called by muse, mutect2, varscan2
- SRGAP1 | c.720G>C p.R240= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV100755170, COSV61895605; called by muse, mutect2
- STMN2 | c.255G>A p.Q85= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV55218603; called by muse, mutect2, varscan2
- SYT17 | c.1137C>T p.F379= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV62545539; called by muse, mutect2, varscan2
- TBC1D1 | c.1750C>T p.L584= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV54715928; called by muse, mutect2, varscan2
- TDRD1 | c.1239C>T p.V413= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs772197336, COSV52588901; called by muse, mutect2, varscan2
- TENM4 | c.6501C>T p.T2167= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs774037488, COSV53616376; called by muse, mutect2, varscan2
- TMED3 | c.375C>T p.P125= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs867880506, COSV55302316; called by muse, mutect2, varscan2
- TMEM214 | c.822G>A p.L274= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV53191975; called by muse, mutect2, varscan2
- TMEM59L | c.768C>T p.L256= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV53241828; called by muse, mutect2, varscan2
- TRAPPC10 | c.1386C>T p.S462= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as rs1408988243, COSV52376137; called by muse, mutect2, varscan2
- TRAPPC10 | c.1632C>G p.L544= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52376146, COSV52376424; called by muse, mutect2, varscan2
- TSHZ2 | c.2076C>T p.I692= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1225807437, COSV61587618; called by muse, mutect2, varscan2
- TSHZ2 | c.2208C>T p.V736= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV61587623; called by muse, mutect2, varscan2
- TTI1 | c.2598G>A p.V866= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV65060951; called by muse, mutect2, varscan2
- TTYH2 | c.1203C>G p.L401= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV53908596, COSV53909344; called by muse, mutect2, varscan2
- UBC | c.1737G>A p.G579= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as rs747097132, COSV100299126; called by muse, mutect2, varscan2
- XDH | c.3894C>T p.D1298= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- ZNF12 | c.1092G>A p.Q364= (on ENST00000405858 / NM_016265.4; = p.Q326= on NM_006956.3) | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV61243858, COSV61244598; called by muse, mutect2, varscan2
- ZNF16 | c.372G>A p.R124= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV52763076; called by muse, mutect2, varscan2
- ZNF671 | c.846G>A p.Q282= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV58051984; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851747 A>G | 3'Flank (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- DCHS2 | n.612G>A | RNA (SNP) | VAF 13/29 reads (45%) | catalogued as COSV59721115; called by muse, mutect2, varscan2
- GAS8 | c.90+1607G>A | Intron (SNP) | VAF 27/62 reads (44%) | catalogued as rs1328985477, COSV51942651; called by muse, mutect2, varscan2
- NUDCD3 | c.509+16993G>A | Intron (SNP) | VAF 97/193 reads (50%) | catalogued as rs1214573168; called by muse, mutect2, varscan2
- SLC25A24 | c.184-6644C>G | Intron (SNP) | VAF 54/187 reads (29%) | catalogued as COSV51446159; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- ZNF99 | c.*1010T>C | 3'UTR (SNP) | VAF 32/104 reads (31%) | catalogued as COSV68055170; called by muse, mutect2, varscan2
